Gene-level copy-number profile of tumor specimen TCGA-44-7669-01A from TCGA case TCGA-44-7669, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.9 years (21,893 days).
Specimen TCGA-44-7669-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e950d7d9-06d5-48d7-925d-f63f8bcf34f7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-7669-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/29696191-9b21-4b7b-9601-ee39b7f44317

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 284; copy number 2: 14,768; copy number 3: 17,376; copy number 4: 21,281; copy number 5: 4,762; copy number 6: 595; copy number 7: 144; copy number 8: 162; copy number 9: 171; copy number 11: 21; copy number 12: 57; copy number 13: 52; copy number 14: 59; copy number 15: 2; copy number 35: 13; copy number 67: 16; copy number 68: 12; copy number 82: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-7669-01A-21D-2062-01): tumor purity 0.5, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 444 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:2,659,937–7,128,889, 167 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr12:57,906,039–57,984,761, 5 genes, copy number 11: ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr14:35,121,846–35,317,474, 2 genes, copy number 35 (within-gene range 2–35): PRORP, AL121594.1.
- chr14:35,219,023–38,371,338, 64 genes, copy number 35–82 (broad region; genes not listed).
- chr14:89,013,386–89,954,659, 16 genes, copy number 67 (within-gene range 2–67): AL137785.1, MPPE1P1, FOXN3, AL138478.1, CAP2P1, AL357093.2, AL357093.1, AL356805.1, AL137230.2, FOXN3-AS1, FOXN3-AS2, RN7SKP107, AL137230.1, Y_RNA, RN7SKP255, CHORDC2P.
- chr18:21,981,121–22,933,764, 16 genes, copy number 11 (within-gene range 5–11): LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2.
- chr18:23,689,453–23,956,222, 1 gene, copy number 12 (within-gene range 5–12): LAMA3.
- chr18:23,957,754–25,352,190, 35 genes, copy number 12: AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr18:26,016,253–27,595,164, 33 genes, copy number 14: SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2.
- chr18:27,932,879–28,177,946, 1 gene, copy number 12 (within-gene range 8–12): CDH2.
- chr18:28,146,233–29,650,440, 9 genes, copy number 12: AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.
- chr18:31,829,197–35,290,245, 52 genes, copy number 13 (within-gene range 6–13): TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2.
- chr18:36,829,106–37,232,172, 1 gene, copy number 12 (within-gene range 6–12): KIAA1328.
- chr18:37,234,119–37,992,413, 10 genes, copy number 12: AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1.
- chr18:43,115,747–43,129,039, 1 gene, copy number 14: AC100779.1.
- chr18:63,123,346–65,652,053, 31 genes, copy number 9–15: BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1.

Autosomal genes at a single copy (total copy number 1): 284. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
